Surgical pathology report (de-identified scan), TCGA case TCGA-LA-A7SW, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Candler, specimen TCGA-LA-A7SW-01A (Primary Tumor).

[page 1 of 4]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT: [REDACTED]	ACCT #: [REDACTED]	LOC: [REDACTED]
REG DR: [REDACTED]	AGE/SX: [REDACTED]	ROOM: [REDACTED]
	DOB: [REDACTED]	BED: [REDACTED]
	STATUS: [REDACTED]	

SPEC #:	RECD:	STATUS:	[REDACTED]
	COLL:	TIME IN FORMALIN:	hrs.
		COLD ISCHEMIA TIME:	mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Left lung mass: lung ca

Remarks:

Specimen(s): A. Level 4R
B. Level 2R
C. Level 5 lymph node
D. Level 5 lymph node
E. Left lung

*ICD-O 3
Carcinoma, squamous cell NOS
88743
Site D Lung, lower lobe
C34.3
J 5/10/13*

MICROSCOPIC DIAGNOSIS

- A. LEVEL 4R LYMPH NODE, MEDIASTINUM, (BIOPSY):
- SCLEROTIC CALCIFIED LYMPH NODE
- NEGATIVE FOR METASTASIS
- B. LEVEL 2R LYMPH NODE, MEDIASTINUM, (BIOPSY):
- NO METASTASIS IN ONE (1) LYMPH NODE
- C. LEVEL 5 LYMPH NODE, MEDIASTINUM, (BIOPSY):
- NO METASTASIS IN ONE (1) LYMPH NODE
- D. LEVEL 5 LYMPH NODE, MEDIASTINUM, (BIOPSY):
- NO METASTASIS IN FOUR (4) LYMPH NODE
- E. LEFT LUNG (PNEUMONECTOMY):
- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH GIANT CELL FEATURES
- TUMOR MEASURES 8.5 CM IN GREATEST DIMENSION
- VISCERAL PLEURAL INVASION PRESENT
- DIRECT EXTENSION OF TUMOR BEYOND LUNG NOT IDENTIFIED
- METASTATIC CARCINOMA IN FOUR (4) OF FOURTEEN (14) PERIBRONCHIAL LYMPH NODES
- RESECTION MARGINS UNINVOLVED WITH BRONCHIAL MARGIN 3.7 CM FROM TUMOR
- CARCINOMA IN SITU NOT IDENTIFIED
- SEE COMMENT FOR SYNOPTIC REPORT

COMMENT(S)

SURGICAL PATHOLOGY CANCER CASE SUMMARY - APPROVED BY COLLEGE OF AMERICAN PATHOLOGISTS

SPECIMEN: Lung

** CONTINUED ON NEXT PAGE **

[page 2 of 4]
RUN DATE:

PAGE 2

RUN TIME:

RUN USER:

User:

SPEC #:

PATIENT:

(Continued)

COMMENT(S)

(Continued)

PROCEDURE: Pneumonectomy
SPECIMEN INTEGRITY: Intact
SPECIMEN LATERALITY: Left
TUMOR SITE: Upper lobe
TUMOR SIZE: 8.5 cm
TUMOR FOCALITY: Unifocal
HISTOLOGIC TYPE: Squamous cell carcinoma
HISTOLOGIC GRADE: G3
VISCERAL PLEURA INVASION: Present
TUMOR EXTENSION: Not applicable
MARGINS: All margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin:
3.7 cm to bronchial margin
LYMPH-VASCULAR INVASION: Not identified
PATHOLOGIC STAGING: Primary tumor: pT3
Regional lymph nodes: pN1
Number of lymph nodes examined: 21
Number of lymph nodes involved: 4
Distant metastasis: not applicable
ADDITIONAL PATHOLOGIC FINDINGS: Focally purulent chronic organizing pneumonia

GROSS DESCRIPTION:

A. Received fresh and labeled "level 4R" is firm, pale-tan tissue measuring 5 x 5 x 2 mm. It is entirely submitted for frozen section block A1.

B. Received fresh and labeled "level 2R" are multiple fragments of red-tan, soft tissue measuring 10 x 10 x 2 mm in aggregate and are entirely submitted for frozen section block B1.

C. Received fresh and labeled "level 5 lymph node" consists of two pieces of blackened, soft tissue compatible with an anthracotic node. They measure together 3 x 1 x 1 cm. Serial sections demonstrate homogenous, black, soft tissue and pale, yellow adipose tissue. No focal, suspicious lesion is identified. One air-dried imprint smear is made. A portion of the node is submitted for frozen section in block C1. The remaining node is submitted for permanent sections in block C2-C3.

Received are two additional parts.

D. Received in formalin labeled with the patient's name and "level 5 lymph node" is a 2.7 x 2.0 x 1.3 cm aggregate of anthracotic, nodular gray-black lymph nodes with focal adherent yellow adipose. The nodes are bisected and individually submitted as labeled with single nodes inked blue to be submitted with bisected nodes:

D1 - one whole lymph node and one bisected lymph node
D2 - one whole lymph node and one bisected lymph node
D3 - one bisected lymph node
D4 - one bisected lymph node

** CONTINUED ON NEXT PAGE **

[page 3 of 4]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 3

User:

SPEC #:

PATIENT:

(Continued)

GROSS DESCRIPTION: (Continued)

E. Labeled "left lung" and received fresh for tumor banking is a 741 gram, 21.0 x 14.0 x 6.0 cm lung. This is the left lung with the expected two lobes. The pleural surface is mildly congested and pink-tan with diffuse anthracotic marbling. The upper lobe is centrally indurated and is sectioned to have an 8.5 x 8.0 x 5.5 cm central cavitated and necrotic tumor mass. There is focal peripheral calcification. Further sectioning shows the mass to be 3.7 cm from the bronchial margin. The parenchyma of the superior upper lobe is mildly congested and spongy. The tumor is in the mid upper lobe, superior to the hilar structures. The parenchyma surrounding the tumor is somewhat consolidated and tan. The tumor does not cross to the lower lobe, however appears to abut the lower lobe. The tumor appears to distort and focally involve the vessels and bronchi of the upper lobe. The bronchi adjacent to the tumor contain opaque, purulent mucus. There are multiple large anthracotic hilar lymph nodes surrounding the bronchus and bronchioles. The lymph nodes appear to be focally positive for tumor. The parenchyma of the lower lobe has similar spongy, mildly congested appearance. There is mild pale parenchyma with focal consolidation in the inferior aspect of the lower lobe. This area may represent mild post-obstructive pneumonia. No additional tumor-like masses are identified.

Representative sections are sampled as labeled:

- E1 - bronchial margin and adjacent lymph node
- E2 - vascular margin
- E3-E5 - sections of tumor to pleura in an area of roughened pleura consistent with adhesion
- E6 - sections showing tumor between upper and lower lobes
- E7 - tumor to surrounding bronchials and vessels
- E8 - perpendicular section down bronchus showing positive bronchial lymph node
- E9-E11 - sections of upper lobe superior (E9), mid (E10) mid and inferior (E11)
- E12-E13 - large peribronchial lymph node
- E14 - one lymph node
- E15 - one lymph node
- E16 - one lymph node
- E17 - three lymph nodes
- E18 - three hilar/peribronchial lymph nodes
- E19-E21 - sections of lower lobe superior (E19), mid (E20) and inferior (E21)

INTRAOPERATIVE CONSULTATION:

A. LEVEL 4R LYMPH NODE, FROZEN SECTION:

- CALCIFIED LYMPH NODE; NO TUMOR SEEN

B. LEVEL 2R LYMPH NODE, FROZEN SECTION:

- NO TUMOR SEEN
- FINDINGS REPORTED TO DR. BY DR. [REDACTED] AT APPROXIMATELY

C. LEVEL 5 LYMPH NODE, FROZEN SECTION:

- NEGATIVE FOR METASTASIS
- FINDINGS TELEPHONED TO DR. IN

E. LEFT PNEUMONECTOMY, GROSS EXAM:

** CONTINUED ON NEXT PAGE **

[page 4 of 4]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 4

User:

SPEC #:

PATIENT:

(Continued)

INTRAOPERATIVE CONSULTATION: (Continued)

- TUMOR IDENTIFIED IN UPPER LOBE AND SAMPLED FOR TISSUE BANKING

PHOTO DOCUMENTATION

Image : Picture Copy Error
Image : Picture Copy Error

Signed ____ (signature on file) ____.

** END OF REPORT **

HIC/NA Discrepancy		✓
Reviewer Initials	Gate Reviewed	

9/23/13
9/18/13

Source: NCI Genomic Data Commons file 8ac1db6c-7fc0-44a0-b2bf-23b48d1435ee (TCGA-LA-A7SW.9835D7E8-2217-4C88-BDE5-DC293B9A505F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).